Gene-level copy-number profile of tumor specimen TCGA-V5-AASX-01A from TCGA case TCGA-V5-AASX, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 74.1 years (27,081 days).
Specimen TCGA-V5-AASX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.d8d39d7a-3c03-45fd-af0b-be7c56149b88.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V5-AASX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/16f76cd6-66f2-45bd-b3bf-a7ea26452779

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 750; copy number 2: 9,574; copy number 3: 33,426; copy number 4: 13,675; copy number 5: 1,875; copy number 6: 116; copy number 7: 176; copy number 8: 47; copy number 9: 148; copy number 12: 18; copy number 13: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V5-AASX-01A-11D-A386-01): tumor purity 0.66, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 397 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:136,553,236–143,557,486, 102 genes, copy number 7 (broad region; genes not listed).
- chr4:143,559,472–143,700,675, 2 genes, copy number 7: GUSBP5, FREM3.
- chr4:166,312,935–170,372,311, 47 genes, copy number 8: Y_RNA, AC097487.1, SPOCK3, RNA5SP171, AC079349.1, RN7SL776P, PHBP14, RN7SKP188, AC105148.1, AC116634.1, ANXA10, AC068989.1, DDX60, DDX60L, AC079926.1, PALLD, BTF3L4P4, PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512.
- chr6:36,243,203–45,377,953, 245 genes, copy number 7–13 (broad region; genes not listed).
- chr6:45,421,079–45,422,005, 1 gene, copy number 13: AL096865.1.

Autosomal genes at a single copy (total copy number 1): 750. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
